Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACV-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : 0

GROSS:

Specimen:

Liver: 12.0 x 11.0 x 7.0 cm, 231.5 gm (fresh)

Gallbladder: 10.0 cm in length, 4.5 cm in diameter, 0.2 cm in thickness (fresh)

Operation: Segmentectomy

Lesion: A well-defined mass

Size: 3.5 x 3.4 x 3.0 cm

Cut surface: Yellowish tan, and granular

Gross type

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 0.2 cm)

Other finding: A nodule (1.1 x 0.9 cm)

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Representative sections are submitted

Gross photo: Present

Blocks

T1-5, TB, bile tinged mass and surrounding liver parenchyme x 6

A, NB, nontumorous liver parenchyme x 2

B, vague nodule and surrounding liver parenchyme x 1

RM, resection margin of liver x 1

GB, gallbladder and cystic duct margin x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

Septum formation: Partial

Surgical resection margin invasion: No

ICD O-3
Carcinoma, hepatocellular NOS
Site Liver C22.0 8170/3
JW 5/19/14

[page 2 of 2]
Serosal invasion: No
Portal vein invasion: No
Microvessel invasion: Yes
Intrahepatic metastasis: No
Multicentric occurrence: No

Non-tumor liver pathology
Liver cirrhosis, HBV-associated
Dysplastic nodule: High grade
Ductal epithelial dysplasia: No
Other liver diseases: No

SPECIAL STAIN: Trichrome shows cirrhotic fibrosis of liver parenchyme

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma,dysplastic nodule
T56000, P10, M81703, dysplastic nodule
gallbladder,ectomy,congestion
T57000, P10, M36141

DIAGNOSIS:

Liver, segment 5, segmentectomy:
Hepatocellular carcinoma
Dysplastic nodule, high grade

Gallbladder, cholecystectomy:
Congestion
Suggestion :

Source: NCI Genomic Data Commons file b1f5e445-43eb-4117-b4ce-97e61662d944 (TCGA-DD-AACV.9BC1D204-8E33-4E30-94B7-6AE5E6484AD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).